Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6141, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6141-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

Right hemicolectomy with en bloc resection of abdominal wall muscle and fascia.

CLINICAL NOTES

PRE-OP DIAGNOSIS: Tumor of cecum.
POST-OP DIAGNOSIS: Same.

GROSS DESCRIPTION

Received fresh for tissue procurement labeled "right hemicolectomy with en bloc" is a previously unopened, 24 cm segment of proximal right colon with attached 17 cm of distal ileum surfaced by smooth to scabrous tan-pink serosa with a moderate amount of attached mesocolon, mesentery and unremarkable omentum. An irregular 5 x 5 x 2.5 cm fragment of red-brown skeletal muscle is present in the vicinity of the cecal pouch. The cauterized surface of the portion of abdominal wall is inked blue (representing true surgical resection margin in that area). A scant amount of adherent omentum and retracted serosal surface are also present in the vicinity of the attached portion of abdominal wall (subsequently inked orange and representing the free radial serosal surface). An unremarkable 7.2 cm in length, 0.9 cm in diameter appendix is present. The proximal and distal margins measure 4 and 8 cm in circumference respectively. On opening, there is a nearly circumferential rubbery tan-white tumor mass at the ileocecal valve measuring 11.0 x 5.7 cm. On sectioning, the tumor has a maximal thickness of 2.8 cm, grossly extending into the muscularis to within 0.5 cm of the inked cauterized resection margin (abdominal wall) (see paired contiguous sections blocks 2&3 and 4&5) and within 0.6 cm of the inked free radial serosal surface (see bisected contiguous sections block 6 and 7). The ileal and remaining colonic mucosa is unremarkable glistening tan-pink with regular folds and the walls average 0.4 cm in thickness. Two palpable rubbery tan-pink-red apical lymph nodes averaging 1.3 cm in greatest dimension are recovered from the attached mesocolon. Numerous additional rubbery pale tan lymph nodes, 2.8 cm in greatest dimension, are recovered from the remainder of the mesocolon and mesentery. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. Representative sections are submitted in 25 blocks as labeled.

BLOCK SUMMARY: 1 - Proximal and distal margins; 2&3, 4&5 - tumor to inked cauterized abdominal wall margin and serosal surface with points of continuity inked red and green respectively; 6&7 - bisected sections, tumor full thickness to inked free radial serosal surface, point of continuity inked black; 8 - tumor to proximal mucosa/at ICV; 9&10 - additional bisected section of tumor to abdominal wall (point of continuity inked violet); 11 - random ileum and colon; 12 - appendix; 13&14 - bisected apical lymph node (one bisected node per cassette); 15&16 - six whole lymph nodes per cassette; 17-21 - one bisected lymph node per cassette; 22&23 - one bisected lymph node (1/2 per cassette); 24&25 - one bisected lymph node (1/2 per cassette).

[page 2 of 2]
[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma, NOS.
Histologic grade: Moderately-differentiated.
Primary tumor (pT): Tumor invades through the muscularis propria into the serosal fat (pT3).
Proximal margin: Negative.
Distal margin: Negative.
Circumferential (radial) margin: Negative.
Vascular invasion: Negative.
Regional lymph nodes (pN): 19 mesenteric lymph nodes are negative for metastatic carcinoma (0/19) (pN0).
Non-lymph node pericolic tumor: Absent.
Distant metastasis (pM): pMx.
Other findings: There is a large area of pericolic abscess formation and inflammatory activity present next to the tumor which has produced adhesion of the abdominal wall to the colon. No direct invasion by tumor is present at that site. Appendix without significant histopathologic finding.

5

DIAGNOSIS

Terminal ileum, appendix, right colon and abdominal wall, en bloc resection:
Invasive moderately-differentiated colonic adenocarcinoma extending through the wall of the cecum into the serosal fat. There are areas of abscess formation and inflammation between the abdominal wall and cecum producing adhesion of the abdominal wall to the colon.
No direct invasion of this area by tumor is present.
The proximal, distal and radial margins of resection are free of tumor. Nineteen mesenteric lymph nodes negative for metastatic carcinoma (0/19). Appendix without significant histopathologic finding.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file d7134bd6-3c05-45c5-a8e8-b4e55b8357d2 (TCGA-A6-6141.1878C2B7-98D8-4797-84F2-30D73D1DB47D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).